Gene-level copy-number profile of specimen HCM-CSHL-0516-C56-85B from HCMI case HCM-CSHL-0516-C56, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mucinous cystic tumor of borderline malignancy; Tissue or organ of origin: Ovary.
Specimen HCM-CSHL-0516-C56-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 3.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 05009afb-1ce4-4b52-b64a-e04cc23eb3ae.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0516-C56-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,219 have no estimate.
https://portal.gdc.cancer.gov/files/95a097bd-e0d2-4484-ad99-49a6737bfd07

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 45; copy number 2: 58,314; copy number 3: 45.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 45. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
